Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7684, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7684-01A (Primary Tumor).

Pathology Report for Subject [REDACTED]

Microscopic Description: Sections demonstrate a moderately hypercellular glial neoplasm that is composed of protoplasmic astrocytes, gemistocytes, microgemistocytes and oligodendroglioma. Focal hypercellular clustering is seen. Atypia is generally mild but is focally moderate. Only a few scattered mitotic figures are seen. Microvascular proliferation is present but necrosis is not seen. There is focally prominent subpial accumulation and invasion into the subarachnoid space is also noted.

Diagnosis:

Anaplastic Oligoastrocytoma, Astrocytoma predominant (WHO grade III).

Source: NCI Genomic Data Commons file ffbe4ce7-3143-4a5b-8d55-972a8b8596de (TCGA-HT-7684.02500CB1-2F28-4624-B001-F5913284295E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).